Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAKG, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAKG-05A (Additional - New Primary).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 2,5 cm; no angio-invasion; no invasion in rete testis; pagetoid invasion in rete testis; no invasion in epididymis; surgical margin spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

ICD O-3

Seminoma NOS 9061/3
Site (R) Testis NOS C62.9

gju 3/7/14

pathologist

professor of pathology

2nd Primary

Criteria	hw 1/18/14	Yes	No

Source: NCI Genomic Data Commons file f96ac059-786b-40e8-8058-f0932be00d2a (TCGA-2G-AAKG.FA4FC6FE-87DF-4000-A4F5-2CE4EBCB310E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).